Somatic mutation profile of tumor specimen BA2779D (aliquot aq-BA2779D) from BEATAML1.0 case 2229, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.3 years (19,464 days).
Specimen BA2779D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f2cf124-415c-407d-8910-48b6891a5885.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2627D (Solid Tissue Normal), aliquot aq-BA2627D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/514274b3-b3b4-41fc-9b58-1b921dac8e24

The open-access MAF lists 17 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Frame Shift Ins 2, In Frame Del 2, Nonsense Mutation 1, 5'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAMK1G | c.1172G>C p.C391S | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.08); catalogued as COSV50525762; called by muse, mutect2, varscan2
- CCDC32 | c.470A>T p.Y157F | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV63634794; called by muse, mutect2, varscan2
- HNF4G | c.653G>A p.R218H (on ENST00000354370 / NM_001330561.2; = p.R265H on NM_004133.5) | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs762541885, COSV62969003; called by muse, mutect2, varscan2
- SEMA5A | c.1094A>G p.Y365C | Missense Mutation (SNP) | VAF 11/252 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.971); catalogued as COSV66807113; called by muse, mutect2
- SUSD4 | c.1027T>C p.F343L | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.97); catalogued as rs1190778540; called by muse, mutect2, varscan2
- TET2 | c.3646C>T p.R1216* | Nonsense Mutation (SNP) | VAF 89/260 reads (34%) | catalogued as rs1009194427, COSV54398925; called by muse, mutect2, varscan2
- TRMT2B | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs376349358; called by muse, varscan2
- TSHZ2 | c.2454dup p.M819Hfs*11 | Frame Shift Ins (INS) | VAF 19/107 reads (18%) | catalogued as rs1193207010; called by mutect2, varscan2
- ADHFE1 | c.1346_1354del p.C449_Q451del | In Frame Del (DEL) | VAF 16/59 reads (27%) | called by mutect2, pindel, varscan2
- ATP7B | c.3793G>T p.V1265L | Missense Mutation (SNP) | VAF 134/326 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FOXN3 | c.1382_1384del p.L461del (on ENST00000261302; = p.L439del on NM_005197.4) | In Frame Del (DEL) | VAF 38/111 reads (34%) | called by mutect2, pindel, varscan2
- MGAM2 | c.2738A>T p.K913M | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PEX5L | c.647C>G p.S216C | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- TET2 | c.4056_4063dup p.A1355Dfs*11 | Frame Shift Ins (INS) | VAF 12/61 reads (20%) | called by mutect2, varscan2
- ZNF107 | c.1045A>T p.I349F | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLK12 | c.180G>A p.A60= | Silent (SNP) | VAF 87/266 reads (33%) | catalogued as rs775724482, COSV99141915; called by muse, mutect2, varscan2
- TMEM176B | c.-1G>T | 5'UTR (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
